Somatic mutation profile of tumor specimen TCGA-56-A4BX-01A (aliquot TCGA-56-A4BX-01A-11D-A24D-08) from TCGA case TCGA-56-A4BX, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.5 years (25,745 days).
Specimen TCGA-56-A4BX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab0391f4-1996-49f2-8adc-5116adc2815c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-A4BX-10A (Blood Derived Normal), aliquot TCGA-56-A4BX-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d6a3d3c-895c-420a-8e03-b674a284e2fc

The open-access MAF lists 148 somatic variants for this specimen: 107 protein-altering or splice-affecting, 39 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 39, Nonsense Mutation 13, Frame Shift Del 2, Nonstop Mutation 1, 3'UTR 1, Splice Site 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 36/44 reads (82%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABR | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 63/72 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV56840589; called by muse, mutect2, varscan2
- ANKS1B | c.2063G>T p.G688V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV100242974, COSV61349472; called by muse, mutect2, varscan2
- ARRDC5 | c.59C>T p.S20L (on ENST00000381781; = p.S6L on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs773823469, COSV104432113; called by muse, mutect2, varscan2
- CASP6 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1441905319; called by muse, mutect2, varscan2
- CD300E | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.78); PolyPhen benign (0.035); catalogued as COSV60790139; called by muse, mutect2, varscan2
- CDKN2A | c.132C>A p.Y44* | Nonsense Mutation (SNP) | VAF 101/120 reads (84%) | catalogued as CM980323, COSV100446627, COSV58689440, COSV58696346, COSV58697475; called by muse, mutect2, varscan2
- CLVS1 | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.656); catalogued as rs766720972; called by muse, mutect2, varscan2
- CTNNA2 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 56/130 reads (43%) | catalogued as COSV100785273; called by muse, mutect2, varscan2
- DCC | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs764081462; called by muse, mutect2, varscan2
- ERICH5 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs752928685; called by muse, mutect2, varscan2
- FAM135B | c.3725C>T p.T1242M | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99424141; called by muse, mutect2, varscan2
- FAM50B | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs746748541, COSV66654790; called by muse, mutect2, varscan2
- GABPA | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100702314; called by muse, mutect2, varscan2
- GASK1B | c.757del p.A253Hfs*22 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as COSV56704800; called by pindel, varscan2
- GPATCH2 | c.429G>T p.W143C | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562117864, COSV65128501; called by muse, mutect2, varscan2
- GPC5 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 76/114 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV65605985; called by muse, mutect2, varscan2
- GRIA4 | c.2644G>C p.V882L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.202); catalogued as COSV56885628; called by muse, mutect2, varscan2
- HECW2 | c.3935G>C p.R1312T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53666849; called by muse, mutect2, varscan2
- HGF | c.1402C>G p.R468G | Missense Mutation (SNP) | VAF 91/98 reads (93%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.454); catalogued as COSV55945497; called by muse, mutect2, varscan2
- KALRN | c.7798A>G p.I2600V (on ENST00000360013 / NM_001024660.4; = p.I903V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.924); catalogued as rs919750972; called by muse, mutect2
- KCTD3 | c.1501A>G p.I501V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.086); catalogued as COSV52069831; called by muse, mutect2, varscan2
- KSR2 | c.570G>T p.W190C | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV60366910; called by muse, mutect2, varscan2
- LRRIQ3 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV63048403; called by muse, mutect2, varscan2
- MEIS3 | c.448-3del | Splice Region (DEL) | VAF 4/24 reads (17%) | catalogued as rs754589852; called by pindel, varscan2
- NEPRO | c.847A>G p.M283V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs762506154; called by muse, mutect2, varscan2
- OR51I2 | c.96C>A p.C32* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV58300095; called by muse, mutect2, varscan2
- OR52E6 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV61431286; called by muse, mutect2, varscan2
- PARP4 | c.2719G>T p.G907C | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as COSV67964681; called by muse, mutect2, varscan2
- PAX6 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | catalogued as CM068277; called by muse, mutect2, varscan2
- PCDHB8 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.72); catalogued as rs141652960; called by muse, mutect2
- POTEE | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as rs543549731; called by muse, varscan2
- RB1 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV57332490; called by muse, mutect2
- RCHY1 | c.91-1G>T p.X31_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as rs1403386813, COSV61008534; called by muse, mutect2
- RXRB | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as rs1317774390, COSV59500940; called by muse, mutect2
- SNX25 | c.76A>G p.R26G | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.185); catalogued as rs1420958242; called by muse, mutect2, varscan2
- SPHK1 | c.46C>T p.R16C (on ENST00000392496 / NM_001355139.2; = p.R30C on NM_021972.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs759686355; called by muse, mutect2, varscan2
- SYT5 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62831546; called by muse, mutect2, varscan2
- TEX44 | c.719C>A p.A240E | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV58355248; called by muse, mutect2, varscan2
- TPH1 | c.935A>G p.Y312C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1464851673, COSV100000821; called by muse, mutect2, varscan2
- USH2A | c.8027C>T p.P2676L | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs754100765, COSV56346721, COSV56399334; called by muse, mutect2, varscan2
- ZIM3 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as rs531319362; called by muse, mutect2, varscan2
- ZNF423 | c.3739G>T p.V1247F (on ENST00000563137 / NM_001379286.1; = p.V1239F on NM_015069.4) | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs911470655, COSV52186843; called by muse, mutect2, varscan2
- AAK1 | c.1840C>T p.Q614* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- ABCA10 | c.2530A>T p.K844* | Nonsense Mutation (SNP) | VAF 102/237 reads (43%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- APOB | c.936C>A p.S312R | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- ATRNL1 | c.1068T>A p.Y356* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- BCL6 | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 34/946 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- CACNA1E | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- CCDC39 | c.2663C>A p.S888* | Nonsense Mutation (SNP) | VAF 52/281 reads (19%) | called by muse, mutect2, varscan2
- CCNB3 | c.2790G>A p.M930I | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCP110 | c.1754A>T p.K585I | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP164 | c.4072del p.E1358Rfs*55 | Frame Shift Del (DEL) | VAF 50/74 reads (68%) | called by mutect2, pindel, varscan2
- DCAF4L2 | c.225C>A p.N75K | Missense Mutation (SNP) | VAF 78/144 reads (54%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX58 | c.197A>T p.E66V | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DHRSX | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DHX34 | c.2003G>T p.R668L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DKK2 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- DUSP22 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DYNC2H1 | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EEF2K | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- FCGBP | c.1210A>T p.I404F | Missense Mutation (SNP) | VAF 116/132 reads (88%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- GASK1B | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- GPR15 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR15 | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSAP | c.1168T>G p.L390V | Missense Mutation (SNP) | VAF 114/126 reads (90%) | SIFT tolerated (0.53); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- H4C8 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2
- HEATR5B | c.2474A>G p.N825S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KSR2 | c.569G>T p.W190L | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.25); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- LDB2 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIMK1 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 189/204 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K13 | c.2573G>C p.G858A | Missense Mutation (SNP) | VAF 157/603 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MCF2L2 | c.2341G>C p.D781H | Missense Mutation (SNP) | VAF 52/766 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2
- MCTP1 | c.2336T>A p.I779N | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MED1 | c.4433A>G p.N1478S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MS4A1 | c.266G>T p.W89L | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A1 | c.267G>T p.W89C | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH6 | c.3018G>T p.Q1006H | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NAV3 | c.3531A>C p.K1177N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- NCK2 | c.1142G>T p.*381Lext*139 | Nonstop Mutation (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2
- OR10G7 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- OR1L4 | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, varscan2
- PARVG | c.422A>T p.H141L | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PDE3B | c.3161G>T p.R1054I | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PGBD2 | c.891G>C p.W297C | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1L1 | c.5468T>G p.L1823R | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- RALGAPA1 | c.1708G>C p.V570L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RNASEL | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ROS1 | c.6734G>T p.G2245V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- RTP1 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 242/601 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SAXO1 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.22); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SEC16A | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- SEMA4F | c.2263A>G p.I755V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEZ6L | c.1838G>T p.R613L | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- SIPA1L1 | c.3203G>T p.W1068L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SIPA1L1 | c.3204G>T p.W1068C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SIRPD | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SLC22A11 | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 80/137 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC34A2 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC5A1 | c.803A>G p.D268G | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- SLCO1A2 | c.344A>T p.Y115F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- SPHKAP | c.2391G>T p.K797N | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SUPT5H | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 155/185 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- SYPL2 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- TMEM220 | c.413C>A p.S138* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- ZNF639 | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 53/491 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2
- ADAM32 | c.975C>T p.L325= | Silent (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- ADGRD1 | c.1002G>T p.L334= | Silent (SNP) | VAF 42/76 reads (55%) | catalogued as COSV55447535, COSV55453046; called by muse, mutect2, varscan2
- ANO3 | c.2332T>C p.L778= | Silent (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- CCDC150 | c.1896G>A p.E632= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs377261997; called by muse, mutect2, varscan2
- CDH10 | c.708C>A p.V236= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV52581016; called by muse, mutect2, varscan2
- DGKD | c.1479C>T p.T493= (on ENST00000264057 / NM_152879.3; = p.T449= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- DIP2C | c.3303G>T p.A1101= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV55181803, COSV99791927; called by muse, mutect2, varscan2
- DMXL2 | c.1878C>T p.V626= | Silent (SNP) | VAF 92/101 reads (91%) | catalogued as rs772410961; called by muse, mutect2, varscan2
- DUSP22 | c.60C>A p.A20= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- FLG | c.11856T>C p.S3952= | Silent (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- GULP1 | c.633G>A p.S211= | Silent (SNP) | VAF 48/151 reads (32%) | catalogued as rs376024527; called by muse, mutect2, varscan2
- HBB | c.381G>T p.V127= | Silent (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- HTR7 | c.1309A>C p.R437= | Silent (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- IQUB | c.576T>G p.V192= | Silent (SNP) | VAF 54/179 reads (30%) | called by muse, mutect2, varscan2
- KCNK10 | c.1383C>T p.L461= | Silent (SNP) | VAF 61/101 reads (60%) | catalogued as COSV56647400; called by muse, mutect2, varscan2
- KMT2C | c.12975G>A p.L4325= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1276343710, COSV51438106; called by muse, mutect2, varscan2
- LRRC56 | c.495G>T p.L165= | Silent (SNP) | VAF 40/62 reads (65%) | called by muse, mutect2, varscan2
- MAML3 | c.2829C>A p.P943= | Silent (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- MYLK2 | c.1737C>A p.A579= | Silent (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- OR10G4 | c.75C>T p.L25= | Silent (SNP) | VAF 16/23 reads (70%) | called by mutect2, varscan2
- OR10G7 | c.75C>T p.L25= | Silent (SNP) | VAF 27/118 reads (23%) | called by muse, mutect2, varscan2
- OR14J1 | c.345G>C p.V115= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as COSV65845633; called by muse, mutect2, varscan2
- OR52B6 | c.30C>A p.I10= | Silent (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- OR6S1 | c.166C>A p.R56= | Silent (SNP) | VAF 58/100 reads (58%) | catalogued as rs1390862722, COSV57838847; called by muse, mutect2
- OR7A5 | c.495G>C p.R165= | Silent (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2
- PASD1 | c.894G>A p.R298= | Silent (SNP) | VAF 32/33 reads (97%) | called by muse, mutect2, varscan2
- PCDH11X | c.528C>T p.Y176= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as rs1362729829, COSV53475888; called by mutect2, varscan2
- PZP | c.747C>A p.V249= | Silent (SNP) | VAF 23/36 reads (64%) | called by muse, mutect2, varscan2
- RBP2 | c.129T>A p.I43= | Silent (SNP) | VAF 49/87 reads (56%) | called by muse, mutect2, varscan2
- SDCBP2 | c.801G>T p.V267= (on ENST00000339987 / NM_001199784.1; = p.V182= on NM_015685.5) | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- SEZ6L | c.1839G>T p.R613= | Silent (SNP) | VAF 64/178 reads (36%) | called by muse, mutect2, varscan2
- SLC39A11 | c.492G>A p.A164= (on ENST00000542342 / NM_001159770.2; = p.A157= on NM_139177.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as rs374851095; called by muse, mutect2
- SPG7 | c.933G>A p.V311= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs1157953850; called by muse, mutect2, varscan2
- ST8SIA1 | c.852G>T p.L284= | Silent (SNP) | VAF 44/65 reads (68%) | called by muse, mutect2, varscan2
- TCTE1 | c.633G>A p.Q211= | Silent (SNP) | VAF 45/68 reads (66%) | catalogued as rs754043154; called by muse, mutect2, varscan2
- TH | c.1281C>T p.Y427= (on ENST00000381178 / NM_199292.3; = p.Y396= on NM_000360.4) | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs375428556; called by muse, mutect2, varscan2
- TRAV27 | c.57C>A p.T19= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs749356799; called by muse, mutect2, varscan2
- UIMC1 | c.1563C>T p.A521= | Silent (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- ZNF496 | c.1317G>T p.V439= | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- MIR134 | n.3G>T | RNA (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1135C>A | 3'UTR (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
